Somatic mutation profile of tumor specimen TCGA-VQ-AA6F-01A (aliquot TCGA-VQ-AA6F-01A-31D-A410-08) from TCGA case TCGA-VQ-AA6F, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 58.0 years (21,170 days).
Specimen TCGA-VQ-AA6F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42835a84-302b-4944-8368-ebbafd9bd97f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-AA6F-10A (Blood Derived Normal), aliquot TCGA-VQ-AA6F-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6f79b18-13d1-4194-86a8-d1a0e7bb7b66

The open-access MAF lists 49 somatic variants for this specimen: 41 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 7, Frame Shift Del 3, Splice Site 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA3 | c.1418T>A p.V473D | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100068650; called by muse, mutect2, varscan2
- AC100868.1 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV51838779, COSV99226191, COSV99226762; called by muse, mutect2
- ADAM22 | c.1085A>G p.K362R | Missense Mutation (SNP) | VAF 24/315 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.706); catalogued as COSV55986757, COSV99715336, COSV99717201; called by muse, mutect2
- APC2 | c.1472T>C p.M491T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1413636202, COSV99279541; called by muse, mutect2
- ATG9A | c.1265+1G>A p.X422_splice | Splice Site (SNP) | VAF 34/89 reads (38%) | catalogued as COSV100772611; called by muse, mutect2, varscan2
- B3GNT9 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs1340774028, COSV99531450; called by muse, mutect2, varscan2
- BCL7A | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.216); catalogued as rs950340443, COSV99947049; called by muse, mutect2
- CALN1 | c.268G>A p.G90S (on ENST00000329008 / NM_001017440.3; = p.G132S on NM_031468.4) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100207405; called by muse, mutect2
- CEP152 | c.4550C>T p.S1517L (on ENST00000380950 / NM_001194998.2; = p.S1461L on NM_014985.4) | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as COSV100358875, COSV57856925; called by muse, mutect2
- DKK2 | c.300C>A p.C100* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as COSV99568992; called by muse, mutect2, varscan2
- FICD | c.1251C>A p.F417L | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV99934125; called by muse, mutect2
- FTSJ3 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs149474852; called by muse, mutect2, varscan2
- KAT6A | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as COSV99704419, COSV99705273; called by muse, mutect2, varscan2
- KIAA0232 | c.2555C>T p.S852L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as rs746490506, COSV56923376; called by muse, mutect2, varscan2
- MAD1L1 | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs747276194, COSV56226118; called by muse, mutect2, varscan2
- MECOM | c.794A>G p.K265R (on ENST00000468789 / NM_001105078.4; = p.K453R on NM_004991.4) | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99244822; called by muse, mutect2
- MICAL3 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99261841; called by muse, varscan2
- NEXN | c.466A>G p.T156A | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); catalogued as COSV99630424; called by muse, mutect2
- NR3C2 | c.928G>T p.V310F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100679213; called by muse, mutect2
- OR2D3 | c.624_627del p.Y209Afs*12 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs1310853985; called by mutect2, pindel
- OR4C12 | c.431C>A p.A144E | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.148); catalogued as COSV100078540; called by muse, mutect2, varscan2
- PCDHA1 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV65372518; called by muse, mutect2, varscan2
- PCOLCE2 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99930741; called by muse, mutect2
- PREX1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs368184718; called by muse, mutect2, varscan2
- PTPN23 | c.1661A>C p.Q554P | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV99650686; called by muse, mutect2, varscan2
- PTPRZ1 | c.6655A>G p.M2219V | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as rs377355175; called by muse, mutect2, varscan2
- RAD9A | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1447309851, COSV100334970; called by muse, mutect2
- RIT2 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs199574261, COSV58665003; called by muse, mutect2, varscan2
- SAMD9 | c.3788C>A p.S1263Y | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs990278730, COSV66073254, COSV66075209; called by muse, mutect2
- SIK2 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1375035996, COSV100516271; called by muse, mutect2
- SLFN11 | c.619T>C p.F207L | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100390689; called by muse, mutect2, varscan2
- SOX15 | c.581A>T p.Q194L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100002100; called by muse, mutect2, varscan2
- STAT5B | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762833594, COSV53186760; called by muse, mutect2, varscan2
- SYN3 | c.1252A>C p.K418Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.95); catalogued as COSV100249250; called by muse, mutect2
- TRIM72 | c.833G>T p.R278M | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV100438566; called by muse, mutect2, varscan2
- ZBTB5 | c.941A>G p.N314S | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.026); catalogued as COSV100312799; called by muse, mutect2, varscan2
- ZNF804B | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV60817557, COSV60835590; called by muse, mutect2
- ARID1A | c.2772_2805del p.M924Ifs*6 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | called by mutect2, pindel
- GBA2 | c.2552C>T p.T851I | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- RHAG | c.209_210del p.T70Ifs*39 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | called by mutect2, pindel, varscan2
- WASHC2C | c.3829C>A p.P1277T (on ENST00000336378; = p.P1256T on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- MYF5 | c.171G>A p.A57= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV57356441; called by muse, mutect2
- NR3C2 | c.930T>A p.V310= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100679211; called by muse, mutect2
- OR2L13 | c.744C>A p.I248= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV100813773, COSV63548505; called by muse, mutect2, varscan2
- P4HB | c.447G>A p.L149= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs1312995866, COSV100515854; called by muse, mutect2, varscan2
- SMARCA1 | c.1149C>G p.L383= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as COSV100946572, COSV64410965; called by muse, mutect2, varscan2
- TIAM1 | c.1260G>A p.P420= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV54537380, COSV54554184; called by muse, mutect2, varscan2
- ZNF324B | c.1266G>A p.E422= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100351682; called by muse, mutect2, varscan2
- WT1 | chr11:32438891 C>G | 5'Flank (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
